Gene-level copy-number profile of tumor specimen TCGA-HT-A5RA-01A from TCGA case TCGA-HT-A5RA, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 65.1 years (23,769 days).
Specimen TCGA-HT-A5RA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.b20d1a96-d227-4ec4-9090-25cf9ceb42e7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HT-A5RA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6646fa27-4b2c-4396-85be-d127a087eb2c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,296; copy number 2: 48,648; copy number 3: 5,593; copy number 4: 46; copy number 5: 79; copy number 6: 82; copy number 7: 39; copy number 8: 1; copy number 24: 2; copy number 25: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HT-A5RA-01A-11D-A288-01): tumor purity 0.85, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 231 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:166,569,693–170,860,993, 78 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:171,058,414–171,460,408, 1 gene, copy number 8 (within-gene range 2–8): TNIK.
- chr3:174,057,641–174,057,864, 1 gene, copy number 5: RN7SKP234.
- chr3:177,019,340–177,228,000, 1 gene, copy number 7 (within-gene range 2–7): TBL1XR1.
- chr3:177,120,691–183,555,706, 120 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr7:54,933,699–55,878,164, 30 genes, copy number 24–25 (within-gene range 2–25): AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2.

Autosomal genes at a single copy (total copy number 1): 5,296. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
